Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A7NF, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A7NF-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, LYMPHADENECTOMY -
SIXTEEN LYMPH NODES, NO EVIDENCE OF METASTATIC CARCINOMA (0/16).

PART 2: LYMPH NODES, LEFT PELVIC, LYMPHADENECTOMY -
THIRTEEN LYMPH NODES, NO EVIDENCE OF METASTATIC CARCINOMA (0/13).

PART 3: PROSTATE, RADICAL PROSTATECTOMY -
A. INVASIVE PROSTATIC ADENOCARCINOMA, GLEASON SCORE 3 + 4 = 7.
B. THE TUMOR INVOLVES BOTH THE RIGHT AND THE LEFT LOBES OF THE PROSTATE AND CONSTITUTES APPROXIMATELY 5% OF THE TOTAL TISSUE EVALUATED.
C. MAXIMAL NODULAR DIMENSION OF THE CARCINOMA IS 1.0 CM.
D. THE CARCINOMA IS CONFINED WITHIN THE CAPSULE OF PROSTATE.
E. ALL INKED MARGINS OF RESECTION ARE FREE OF CARCINOMA.
F. BILATERAL SEMINAL VESICLES, NO EVIDENCE OF CARCINOMA SEEN.
G. PERINEURAL INVASION BY THE CARCINOMA IS IDENTIFIED.
H. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN) IS SEEN.
I. TNM STAGE: T2c N0 MX.
J. HISTOLOGIC GRADE: G3 (POORLY DIFFERENTIATED).

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA: PSA value: 4.6
INVASIVE CA IDENTIFIED?: Yes
TUMOR HISTOLOGY: Adenocarcinoma NOS
PRIMARY GLEASON GRADE: 3
SECONDARY GLEASON GRADE: 4
GLEASON SUM SCORE: 7
GLEASON 4/5 PERCENTAGE: 25%
WEIGHT OF PROSTATE: 51.8gm
TUMOR SIZE: Maximum dimension: 1.0 cm
LOBE LATERALITY: Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR: 5 - 25%
MULTIFOCAL DISEASE: Yes
HIGH GRADE PIN: Yes - multifocal
EXTRAPROSTATIC EXTENSION: No
PERINEURAL INVASION: Yes
ANGIOLYMPHATIC INVASION: No
SEMINAL VESICLE INVASION: No
SURGICAL MARGIN INVOLVEMENT: All surgical margins free of tumor
RESIDUAL TUMOR: R0
LYMPH NODES EXAMINED: 29
LYMPH NODES POSITIVE: 0
T STAGE, PATHOLOGIC: pT2c
N STAGE, PATHOLOGIC: pN0
M STAGE, PATHOLOGIC: pMX
HISTOLOGIC GRADE: G3-4, Poorly differentiated/undifferentiated

CLIN ICD O-3
Adenocarcinoma, acinar
path 8/40/13
Adenocarcinoma NOS
8/40/13
Site: Prostate NOS
061.9
9/24/13

MPA Discrepancy		☒
Diagnosis/Synchronous Primary Node		☒

Source: NCI Genomic Data Commons file b05d1349-399d-4549-921b-6af678e2c09c (TCGA-EJ-A7NF.1487F0B2-58BB-41C3-B23F-F51676796AA7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).